Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TJ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TJ-01A (Primary Tumor).

[page 1 of 5]
ICD 03
Astrocytoma, grade III 9401/3
Site: Brain, supratentorial NOS C71.0
B Brain, temporal lobe C71.2
JW 4/22/14

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: M Acct: Reported:
Physician(s):
Phy Location:

Clinical History

-year-old man experiences headaches, memory problems, imbalance, and seizure. On imaging, there is lesion in the right inferior temporal lobe, with mass effect and questionable enhancement.

Operative Diagnoses

Brain tumor

Operation / Specimen

A: Brain, right temporal, craniotomy

Pathologic Diagnosis

Brain, right temporal, excisional biopsy:

1. Diffuse astrocytoma, high grade, consistent with anaplastic astrocytoma, WHO grade 3
2. Negative for co-deletion of chromosomal arms 1p and 19q
3. Negative for IDH1/ IDH2 mutation
4. Ki-67/ MIB-1 proliferation index: up to approximately 10%

See Comment.

Comment

The portions of cerebrum show an infiltrating glial neoplastic proliferation that has an astrocytic phenotype. Mitotic figures are identified, and the Ki-67/ MIB-1 proliferation index is greater than 10%. There are abnormal blood vessels, with a mitosis identified in the endothelial layer of one vessel. There is no tumor necrosis seen. Overall, the sections predominantly show a high histological grade diffuse glioma that is most consistent with anaplastic astrocytoma, WHO grade 3. However, the presence of mitosis in an abnormal blood vessel, as well as patchy post-contrast enhancement seen in the pre-operative radiology imaging studies, raise concern for these sections representing the periphery of a higher grade diffuse astrocytoma, i.e. glioblastoma. Correlation with radiology imaging studies is recommended for the overall clinicopathological diagnosis.

Electronically Signed Out

Consultant: Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Surgical Pathology

Page 2 of 5

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

LOW POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A3)
H and E slide was examined and tumor DNA was enriched by microdissection

[page 2 of 5]
TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S552, D19S219, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A3). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

Surgical Pathology

Page 3 of 5

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug

[page 3 of 5]
Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

, Senior Staff Pathologist

IDH1 Mutation Detection Assay

Date Ordered:

Date Reported:

Interpretation

NEGATIVE - There is no evidence of IDH1 point mutation, as indicated by the absence of any nucleotide changes in codon 132 of the IDH1 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

TEST DESCRIPTION: IDH1 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block (A3)

H and E slide was examined and tumor DNA was enriched by microdissection

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional

sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food

and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These

results are provided for informational purposes only, and should be interpreted only in the context of established

procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

IDH2 Mutation Detection Assay

Date Ordered:

Date Reported:

Interpretation

Surgical Pathology

[page 4 of 5]
NEGATIVE - There is no evidence of IDH2 point mutation, as indicated by the absence of any nucleotide changes in codon 172 of the IDH2 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

TEST DESCRIPTION: IDH2 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block (A3)

H and E slide was examined and tumor DNA was enriched by microdissection

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in

majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional

sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food

and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These

results are provided for informational purposes only, and should be interpreted only in the context of established

procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Intra-Operative Consultation

A. Brain tumor, excision biopsy: Astrocytic neoplastic proliferation with atypical features (C/W infiltrative glioma,

R/O/R/I anaplastic astrocytoma, other). Touch preparation smears performed at

and results reported to the Physician of Record.

Staff Pathologist

Gross Description

A. Brain tumor, excision biopsy:

CONTAINER LABEL: Brain tumor frozen/permanent. FIXATIVE: None.

GENERAL: Two fragments, 3 cm in aggregate diameter, of semi firm, creamy-white cerebral cortex and white matter,

submitted for intraoperative evaluation. The cortical - white mater interphase is ill-defined.

Representatives are

submitted for cytological preparations.

SECTIONS: Entirely submitted in A1 - A3.

Microscopic Description

[page 5 of 5]
The frozen section diagnosis is confirmed on the permanent sections.

IMMUNOHISTOCHEMISTRY: The neoplastic cells are negative for the mutant IDH1-R132H protein.

CD163 depicts

essentially unremarkable perivascular microglia only.

Surgical Pathology

Page 5 of 5

ICD-9(s): 237.5 237.5 191.9

Billing Fee Code(s): A:

IDH1:

IDH2:

LOH 1p19q:

MGMT:

Source: NCI Genomic Data Commons file 3aa2126c-ad85-4982-997a-264a0641c0b7 (TCGA-DU-A7TJ.039F34B6-70E4-42E2-A93C-AD9BEDAC507D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).